Surgical pathology report (de-identified scan), TCGA case TCGA-D6-8569, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-8569-01A (Primary Tumor).

Unit in charge: L - [REDACTED]

Physician in charge: [REDACTED]

Clinical diagnosis (suspicion): **Tumour of the tongue and floor of the mouth, left side.**

Date of admission: [REDACTED] (urgency: Standard)

Material:

1) Material: mouth - tongue. Method of collection: Please examine the marked margin. Method of collection: Collection of specimens for direct examination

Histopathological diagnosis:

Examination performed on: [REDACTED]

Carcinoma planoepitheliale keratodes invasivum linguae. G2, pT2. [REDACTED]

Invasive keratinizing squamous carcinoma of the tongue

Macroscopic description:

Surgical segment sized 3.5 x 3 x 1.5 cm with the tumour sized 2.4 x 2 x 0.9 cm.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum G2.

Minimum margin of healthy tissues to the side of the surgical specimen: 0.4 cm Minimum margin of healthy tissues from the base of the surgical specimen: 0.6 cm. No proliferation into vessels and nerve stems found.

Assistant:

Pathologist: : [REDACTED]

Result of intraoperative examination

Examination performed on: [REDACTED]

1-4 No neoplastic lesions found.

Final reply to be given after full material is developed

Assistant: [REDACTED]

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 5386495d-2c1d-4e5e-8c31-b75b072884eb (TCGA-D6-8569.EFEB49CA-C5AE-4B11-9504-4CA818A0B582.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).